Somatic mutation profile of tumor specimen TCGA-AA-A02W-01A (aliquot TCGA-AA-A02W-01A-01W-A00E-09) from TCGA case TCGA-AA-A02W, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 73.1 years (26,693 days).
Specimen TCGA-AA-A02W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e28c515-20fa-4ae1-b2ff-5aebf22ccc7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02W-10A (Blood Derived Normal), aliquot TCGA-AA-A02W-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b3c5a99-9d77-49d0-bef0-c15a7f722408

The open-access MAF lists 99 somatic variants for this specimen: 70 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 28, Nonsense Mutation 8, Splice Site 4, Frame Shift Del 2, RNA 1, In Frame Del 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.6453C>T p.C2151= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as rs794728251, CM940769, CS118012, COSV57318600; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 32/50 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 65/89 reads (73%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs555477715, COSV63664187; called by muse, mutect2, varscan2
- ADAM29 | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs150047888, COSV63661943; called by muse, mutect2, varscan2
- ADGRF1 | c.1694A>C p.H565P | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51945824; called by muse, mutect2, varscan2
- APC | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 50/150 reads (33%) | catalogued as COSV57322620, COSV57331090; called by muse, mutect2, varscan2
- ASB17 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1470435631, COSV52410605, COSV52412587; called by muse, mutect2, varscan2
- C2orf16 | c.404_407del p.M135Tfs*14 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | catalogued as COSV68646221; called by mutect2, varscan2
- CCDC6 | c.1231-2A>G p.X411_splice | Splice Site (SNP) | VAF 15/36 reads (42%) | catalogued as COSV54060488, COSV99569253; called by muse, mutect2, varscan2
- CLCN4 | c.2190C>T p.S730= | Splice Region (SNP) | VAF 18/106 reads (17%) | catalogued as rs778033301, COSV66466769; called by muse, mutect2
- COL22A1 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.413); catalogued as rs747819697, COSV57339361; called by muse, mutect2, varscan2
- DCAF4L2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747432904, COSV60479126, COSV60479633; called by muse, mutect2, varscan2
- ETFA | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781400558, COSV51211641; called by muse, mutect2, varscan2
- FGD5 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as COSV53244247; called by muse, varscan2
- FOXO4 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs758569871, COSV58575423; called by muse, mutect2, varscan2
- GRK1 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs762974373, COSV100175448, COSV59552976; called by muse, mutect2, varscan2
- GRM7 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63128926; called by muse, mutect2, varscan2
- HECTD4 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV66392910; called by muse, mutect2, varscan2
- IL13RA1 | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65426472; called by muse, mutect2
- KCNA4 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 147/327 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60252776; called by muse, mutect2, varscan2
- KLHL7 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | catalogued as COSV59161861; called by muse, mutect2, varscan2
- KRT74 | c.390C>A p.D130E | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59771670; called by muse, mutect2, varscan2
- L1CAM | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs782070899, COSV62828384; called by muse, mutect2
- LIM2 | c.278C>A p.S93Y (on ENST00000596399 / NM_001161748.2; = p.S135Y on NM_030657.4) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV55741323; called by muse, mutect2, varscan2
- LRP1B | c.3260G>T p.G1087V | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV67227620; called by muse, mutect2, varscan2
- LYST | c.11299T>C p.Y3767H | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1253169967, COSV67707677; called by muse, mutect2, varscan2
- MEIS3 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs752747235, COSV58983729; called by muse, mutect2, varscan2
- METTL2B | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 59/563 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771135202, COSV52309086; called by muse, mutect2, varscan2
- MICALL1 | c.2002C>G p.L668V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV53241001; called by muse, mutect2, varscan2
- MYO5A | c.2620C>T p.R874W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1418196344, COSV62560848; called by muse, mutect2, varscan2
- NCALD | c.111C>A p.D37E | Missense Mutation (SNP) | VAF 36/552 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV99636876; called by muse, mutect2
- NCOA1 | c.3881+1G>C p.X1294_splice | Splice Site (SNP) | VAF 12/200 reads (6%) | catalogued as COSV99945470; called by muse, mutect2
- NEXMIF | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs777607570, COSV50027401, COSV99279917; ClinVar: likely benign; called by muse, mutect2, varscan2
- NTN4 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371661550, COSV59218112; called by muse, mutect2, varscan2
- OR6N2 | c.458T>G p.F153C | Missense Mutation (SNP) | VAF 19/357 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100210002; called by muse, mutect2
- PADI4 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1456388353, COSV64924091; called by muse, mutect2, varscan2
- PCDHB13 | c.2014C>A p.P672T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV53397231; called by muse, mutect2, varscan2
- PRPF40B | c.929G>T p.R310L (on ENST00000380281; = p.R304L on NM_012272.3) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV56058370, COSV56059670; called by muse, mutect2, varscan2
- PRRC2A | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1221489101, COSV63224619; called by muse, mutect2, varscan2
- PTPRT | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61974113, COSV61985449, COSV62035189; called by muse, mutect2, varscan2
- RAPH1 | c.226+1G>C p.X76_splice | Splice Site (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100051247; called by muse, mutect2, varscan2
- REN | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745900131, COSV65817849; called by muse, mutect2, varscan2
- RNASE11 | c.524C>A p.T175N | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60087731; called by muse, mutect2
- SAMHD1 | c.1352G>C p.R451P | Missense Mutation (SNP) | VAF 80/423 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53429981; called by muse, mutect2, varscan2
- SLCO1B1 | c.482-1G>T p.X161_splice | Splice Site (SNP) | VAF 96/424 reads (23%) | catalogued as COSV99918141; called by muse, mutect2, varscan2
- SOGA3 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324241996, COSV64106840; called by muse, mutect2, varscan2
- SON | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as rs755601747, COSV51659418; called by muse, mutect2, varscan2
- SORT1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56667761; called by muse, mutect2
- STIM1 | c.1889T>C p.V630A | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV56155444; called by muse, varscan2
- SYNE1 | c.15991C>A p.Q5331K (on ENST00000367255 / NM_182961.4; = p.Q5260K on NM_033071.3) | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54998093; called by muse, mutect2, varscan2
- TEX47 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs774856236, COSV51879143, COSV99787186; called by muse, mutect2, varscan2
- TG | c.1514G>A p.G505D | Missense Mutation (SNP) | VAF 223/471 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.24); catalogued as COSV99599603; called by muse, mutect2, varscan2
- TMEM215 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61363545; called by muse, mutect2, varscan2
- TP53TG5 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as COSV65577582; called by muse, mutect2, varscan2
- TRIM24 | c.3104C>T p.P1035L (on ENST00000343526 / NM_015905.3; = p.P1001L on NM_003852.4) | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58972998; called by muse, mutect2, varscan2
- TTN | c.16354G>T p.E5452* (on ENST00000591111; = p.E4525* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 55/219 reads (25%) | catalogued as COSV60103888; called by muse, mutect2, varscan2
- TTN | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | catalogued as rs150954246, COSV60095193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13C | c.5881G>A p.A1961T (on ENST00000644861 / NM_020821.3; = p.A1918T on NM_017684.5) | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV99827627; called by muse, mutect2, varscan2
- WWP1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749190769, COSV55359752; called by muse, mutect2, varscan2
- ZNF20 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as rs960832703, COSV100502884; called by muse, mutect2, varscan2
- ZNF26 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 75/130 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.142); catalogued as rs115196721, COSV60806839; called by muse, mutect2, varscan2
- ZNF827 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 40/121 reads (33%) | catalogued as COSV65227768; called by muse, mutect2, varscan2
- ZNF91 | c.1739G>T p.G580V | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56085446; called by muse, mutect2, varscan2
- ZNF91 | c.44T>A p.F15Y | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV56085454; called by muse, mutect2, varscan2
- ABCC4 | c.1036_1059del p.I346_V353del | In Frame Del (DEL) | VAF 2828/3680 reads (77%) | called by pindel, varscan2
- CDCA7L | c.1149C>A p.C383* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- DHX8 | c.3594_3595insAAT p.L1198_E1199insN | In Frame Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- NBPF11 | c.2543A>C p.E848A | Missense Mutation (SNP) | VAF 85/521 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- UTP18 | c.701_702del p.G234Dfs*13 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- APPL2 | c.1521C>T p.D507= | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as COSV99314518; called by muse, mutect2
- ATG13 | c.894T>C p.P298= | Silent (SNP) | VAF 32/952 reads (3%) | called by muse, mutect2
- ATP6V1C2 | c.348G>A p.P116= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs746366093, COSV55359628; called by muse, mutect2
- CARD14 | c.2130C>T p.F710= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV60123956; called by muse, mutect2, varscan2
- DCLK3 | c.1350G>A p.P450= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as rs528794239, COSV101373994, COSV69363342; called by muse, mutect2, varscan2
- DMD | c.8850G>A p.L2950= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV58915011; called by muse, mutect2, varscan2
- DYNC1H1 | c.12018C>T p.H4006= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV64137639; called by muse, mutect2, varscan2
- FBXO10 | c.711C>T p.N237= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs371415820; called by muse, mutect2, varscan2
- FCGBP | c.10488C>T p.D3496= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs771508776; called by muse, mutect2, varscan2
- GPC4 | c.589C>T p.L197= | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- HLA-DQA1 | c.246G>A p.P82= | Silent (SNP) | VAF 10/324 reads (3%) | catalogued as rs1332177306; called by muse, mutect2
- KIR3DL2 | c.201C>T p.H67= | Silent (SNP) | VAF 70/170 reads (41%) | catalogued as rs766660967; called by muse, mutect2, varscan2
- KRT13 | c.687C>T p.I229= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs779846006, COSV55840137; called by muse, mutect2, varscan2
- MED13L | c.2295G>A p.V765= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV56121157, COSV56132979; called by muse, mutect2, varscan2
- NDST1 | c.1113C>T p.D371= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs139282708; called by muse, mutect2
- NLGN4X | c.1173G>A p.T391= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs776424128, COSV52020724; called by muse, mutect2, varscan2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1340855486, COSV55505013; called by muse, mutect2, varscan2
- PCDHB5 | c.1080G>A p.P360= | Silent (SNP) | VAF 50/165 reads (30%) | catalogued as rs782047381, COSV50653745; called by muse, mutect2, varscan2
- PHF20L1 | c.2595G>A p.K865= | Silent (SNP) | VAF 50/389 reads (13%) | catalogued as COSV55193424; called by muse, mutect2, varscan2
- PPP1R32 | c.966C>T p.S322= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as COSV58545016; called by muse, mutect2, varscan2
- SLITRK1 | c.2040A>C p.A680= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV65676056; called by muse, mutect2, varscan2
- ST8SIA5 | c.858G>A p.S286= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV59332274; called by muse, mutect2, varscan2
- TLL1 | c.2880G>T p.V960= | Silent (SNP) | VAF 27/427 reads (6%) | catalogued as COSV50325027, COSV50327204; called by muse, mutect2
- UGT2B11 | c.499C>A p.R167= | Silent (SNP) | VAF 72/239 reads (30%) | catalogued as rs148268917, COSV71423456; called by muse, mutect2
- UNC80 | c.564C>T p.F188= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as rs755184462, COSV99777986; called by muse, mutect2, varscan2
- ZNF98 | c.279C>T p.D93= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV63335665; called by muse, mutect2, varscan2
- ZNRF4 | c.885G>A p.Q295= | Silent (SNP) | VAF 87/111 reads (78%) | catalogued as rs1351174667, COSV55774499; called by muse, mutect2, varscan2
- RPL23AP42 | n.14C>T | RNA (SNP) | VAF 124/243 reads (51%) | catalogued as rs1356622878; called by muse, mutect2, varscan2
